Somatic mutation profile of tumor specimen 0DUIXR from CCDI case PBCLKL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Schwannoma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 17.9 years (6,527 days).
Specimen 0DUIXR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e53ba05-24bf-4e53-a4f0-9be935a421a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUIWU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4040ee69-c490-49e6-9463-c96299dc9e33

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, mutect2
- CACNA1E | c.3087C>A p.S1029R | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2
- DNAH6 | c.9032C>A p.A3011D | Missense Mutation (SNP) | VAF 45/539 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.051); called by muse, mutect2
- ERBB3 | c.713C>G p.P238R | Missense Mutation (SNP) | VAF 16/512 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2
- RYR3 | c.5325G>T p.E1775D | Missense Mutation (SNP) | VAF 25/679 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2
- SH3RF2 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 26/838 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ASCL2 | c.-82T>C | 5'UTR (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- IKZF1 | c.161-8200G>A | Intron (SNP) | VAF 87/515 reads (17%) | catalogued as rs922355666; called by muse, mutect2, varscan2
- MAP4K1 | c.1447-84G>A | Intron (SNP) | VAF 3/17 reads (18%) | catalogued as rs1465355321; called by muse, varscan2
